TARGET case TARGET-15-SJMPAL011911 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/80256ffa-fff5-46f1-a6ec-5b835b830010

Demographics
Sex at birth: male; Age at index: 15 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 15.7 years (5,731 days); Year of diagnosis: 2010; Days to last follow up: 2,034 days (5.6 years).

Follow-up (1 entry)
- Days to follow up: 2,034 days (5.6 years); Event-free: no event (relapse, second malignancy or death) recorded through day 2,034; Year of follow up: 2015.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0: Leukocytes 146 ×10³/µL.

Biospecimens (3 samples)
- Samples TARGET-15-SJMPAL011911-03A, TARGET-15-SJMPAL011911-03A.1 (2 with the same recorded description): Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
- Sample TARGET-15-SJMPAL011911-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Overall Survival Time in Days: 2034
- Protocol: St. Jude
- WBC at Diagnosis: 145.6
- Initial Therapy: AML
- Karyotype: 46,XY[20]
- WHO ALAL Classification: T/M
- WHO Dx: T/M
